Somatic mutation profile of tumor specimen 0DP2CW from CCDI case PBCCZR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.4 years (5,275 days).
Specimen 0DP2CW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e91d4418-82e7-4c60-90fd-649fbad156e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP2CE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c63561f-1043-4ddf-ad44-a79a4649f7fb

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Splice Site 1, Nonsense Mutation 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH5 | c.8875G>A p.G2959R | Missense Mutation (SNP) | VAF 272/1585 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147443285; called by muse, mutect2, varscan2
- EPHA8 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 32/768 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1394031937, COSV51263170; called by muse, mutect2
- FRY | c.3760G>A p.D1254N | Missense Mutation (SNP) | VAF 48/1028 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs930237165, COSV104430871; called by muse, mutect2
- MEGF8 | c.6770G>A p.R2257H (on ENST00000251268 / NM_001271938.2; = p.R2190H on NM_001410.3) | Missense Mutation (SNP) | VAF 84/892 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.7); catalogued as rs376007307; called by muse, mutect2
- NCOR1 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 237/1460 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs190110703, COSV51995901, COSV51997485, COSV52003388; called by muse, mutect2, varscan2
- PTPN5 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 115/619 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs759780758, COSV60030523; called by muse, mutect2, varscan2
- DENND2C | c.2668+2T>C p.X890_splice (on ENST00000393274 / NM_001256404.2; = p.X833_splice on NM_198459.4) | Splice Site (SNP) | VAF 122/840 reads (15%) | called by muse, mutect2, varscan2
- ITGA11 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 20/580 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, mutect2
- TMEM45B | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 44/1467 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2
- VPS13B | c.5917C>T p.Q1973* | Nonsense Mutation (SNP) | VAF 70/1877 reads (4%) | called by muse, mutect2
- COL4A6 | c.2970A>G p.G990= | Silent (SNP) | VAF 41/502 reads (8%) | called by muse, mutect2
- NAPB | c.786+42T>G | Intron (SNP) | VAF 31/796 reads (4%) | called by muse, mutect2
